Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6863, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6863-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted]

Formatted Path Report

[Redacted]	[Redacted]	[Redacted]		
------------	------------	------------	--	--

[page 2 of 3]
	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Anterior resection of rectum Specimen size: Not specified Tumor site: Rectum Tumor size: 4.5 x 3 x 1 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 3/6 positive for metastasis (Pararectal 3/6) Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	---

Source: NCI Genomic Data Commons file 765116a3-bddd-4df5-b00d-664166f06b67 (TCGA-F5-6863.D9E6E524-72F9-4EB7-8D10-0EA4501451F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).